Somatic mutation profile of tumor specimen TCGA-EM-A22I-01A (aliquot TCGA-EM-A22I-01A-11D-A17V-08) from TCGA case TCGA-EM-A22I, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 52.0 years (19,003 days).
Specimen TCGA-EM-A22I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e8ef66e-599c-49e8-a2bb-9167231203ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22I-10A (Blood Derived Normal), aliquot TCGA-EM-A22I-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66ea3424-201c-485f-87fb-df16ec83e2a8

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARFGEF2 | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64213625; called by muse, mutect2, varscan2
- LRRCC1 | c.2598T>A p.D866E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64484332; called by muse, mutect2, varscan2
- PKD1L1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200343133, COSV56963991, COSV99221622; called by muse, mutect2, varscan2
- RC3H2 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59012748; called by muse, mutect2
- ZFHX3 | c.4783C>G p.P1595A | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51726104; called by muse, mutect2, varscan2
- C10orf99 | c.204G>A p.E68= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV64532052; called by muse, mutect2
- CACNB1 | c.1197G>A p.E399= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1355097592, COSV59999355; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504894 del TAAA | 5'Flank (DEL) | VAF 9/27 reads (33%) | catalogued as rs1350369274; called by pindel, varscan2
